Somatic mutation profile of tumor specimen TCGA-VR-A8ER-01A (aliquot TCGA-VR-A8ER-01A-11D-A36J-09) from TCGA case TCGA-VR-A8ER, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 54.6 years (19,951 days).
Specimen TCGA-VR-A8ER-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2c02a84-d0e5-4d39-beaa-2f632346724b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8ER-10A (Blood Derived Normal), aliquot TCGA-VR-A8ER-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2217042-b9c9-4ab1-86da-95b18507e98e

The open-access MAF lists 55 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 9, Nonsense Mutation 3, Frame Shift Del 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APPBP2 | c.1757G>T p.*586Lext*70 | Nonstop Mutation (SNP) | VAF 7/86 reads (8%) | catalogued as COSV50028614; called by muse, mutect2
- ASH1L | c.7497G>T p.Q2499H (on ENST00000368346 / NM_001366177.2; = p.Q2494H on NM_018489.3) | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV64207044; called by muse, mutect2, varscan2
- DCP1A | c.1211A>G p.H404R | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as rs375539952; called by muse, mutect2, varscan2
- DEF8 | c.397C>T p.R133C (on ENST00000268676 / NM_207514.3; = p.R72C on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs779640162; called by muse, mutect2, varscan2
- DOCK11 | c.6211G>A p.A2071T | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs766718965, COSV52249181; called by muse, mutect2, varscan2
- ERBIN | c.2651A>G p.Y884C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs747561237; called by muse, mutect2, varscan2
- FSTL5 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60227175; called by muse, mutect2, varscan2
- GRAP | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs755441479, COSV52413055; called by muse, mutect2, varscan2
- GUCA1B | c.448T>C p.F150L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.58); catalogued as rs767596914; called by muse, mutect2, varscan2
- LEO1 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs754922458, COSV55175212; called by muse, mutect2, varscan2
- OR5H1 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV63402990, COSV99075120; called by muse, mutect2, varscan2
- SCAF4 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99741290; called by muse, mutect2, varscan2
- SCUBE3 | c.746G>A p.S249N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51458727; called by muse, mutect2, varscan2
- SEMA4F | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.581); catalogued as rs778118707, COSV60281939; called by muse, mutect2, varscan2
- THSD4 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs766502435; called by muse, mutect2, varscan2
- TP53 | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV52680014, COSV52741118, COSV52987587, COSV53109055; called by muse, varscan2
- ZNF254 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV100741720; called by muse, mutect2, varscan2
- ZNF257 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV101447968, COSV99078261; called by muse, mutect2, varscan2
- ACSM5 | c.998C>A p.T333N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- APEX2 | c.572A>T p.H191L | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CATSPERB | c.2702T>A p.M901K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP10 | c.1627T>A p.Y543N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ENPP4 | c.482A>G p.E161G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ESPL1 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- GOLGB1 | c.9633C>A p.N3211K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IQGAP1 | c.14A>G p.D5G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ITGB5 | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- MAP1B | c.4269A>T p.R1423S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MTF2 | c.1315A>G p.I439V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCEH1 | c.191A>G p.K64R (on ENST00000538775; = p.K32R on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PHYHD1 | c.677T>C p.L226P (on ENST00000372592 / NM_001100876.2; = p.S219P on NM_174933.4) | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PIP4K2B | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- R3HDM2 | c.1658C>A p.P553Q | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- RBM5 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- RUNX2 | c.1115A>T p.D372V (on ENST00000371438; = p.D350V on NM_001015051.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RYR3 | c.10277G>A p.W3426* (on ENST00000389232; = p.W3427* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- SLC30A5 | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SPG11 | c.4597A>T p.S1533C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC14 | c.2070C>G p.H690Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- WWC1 | c.902_923del p.K301Mfs*11 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- XPR1 | c.53A>C p.Q18P | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF140 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- ZXDB | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABTB2 | c.1899C>T p.P633= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as rs770117269; called by muse, mutect2, varscan2
- AMH | c.501C>T p.Y167= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs779588404; called by muse, mutect2, varscan2
- RAB2A | c.258C>T p.Y86= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs759231678; called by muse, mutect2, varscan2
- SPATA31D1 | c.1521C>T p.L507= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as COSV100782833; called by muse, mutect2, varscan2
- TOMM70 | c.594G>A p.E198= | Silent (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- TRPS1 | c.1917C>T p.S639= (on ENST00000220888 / NM_001330599.2; = p.S652= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV55233136; called by muse, varscan2
- UBR1 | c.444C>T p.F148= | Silent (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- USP46 | c.243G>A p.A81= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs531415307, COSV101484247; called by muse, mutect2, varscan2
- ZNF548 | c.1272C>T p.S424= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1010483790, COSV60240248; called by muse, mutect2, varscan2
- FTH1 | c.-1C>A | 5'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs1420961775; called by muse, mutect2
